Somatic mutation profile of tumor specimen TCGA-2G-AALR-01A (aliquot TCGA-2G-AALR-01A-21D-A42Y-10) from TCGA case TCGA-2G-AALR, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8b0d1ca-b20f-44a7-bcba-da5091e088dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AALR-10A (Blood Derived Normal), aliquot TCGA-2G-AALR-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f13806f0-9f9e-41a5-95e3-240c5abc1698

The open-access MAF lists 46 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 7, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1093G>C p.V365L | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs782518797; called by muse, mutect2
- ADGRV1 | c.9642C>G p.I3214M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV67984735; called by muse, mutect2, varscan2
- CCR10 | c.682G>C p.A228P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1031510359; called by muse, mutect2, varscan2
- CD1E | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV63769885; called by muse, mutect2
- CLCA1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs773277903; called by muse, mutect2
- MGAT4B | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs372861672; called by mutect2, varscan2
- NDUFS3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV55454204; called by muse, mutect2
- PIK3CD | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.327); catalogued as rs762320758, COSV100740347; called by muse, mutect2
- SMOC1 | c.1300G>C p.V434L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.077); catalogued as rs192204434; called by muse, mutect2, varscan2
- SPTBN4 | c.6335C>T p.T2112M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100152163; called by muse, mutect2, varscan2
- SVEP1 | c.8104G>A p.D2702N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs751242118, COSV99927931; called by muse, mutect2, varscan2
- TMCO2 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV65647038; called by muse, mutect2, varscan2
- USP20 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs540729891; called by muse, mutect2, varscan2
- ZNF300 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51035624; called by muse, mutect2, varscan2
- APC | c.8083A>G p.K2695E | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); called by muse, mutect2
- ARHGEF6 | c.1563C>G p.N521K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GABRP | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRIP1 | c.2950C>A p.L984M (on ENST00000359742 / NM_001379345.1; = p.L932M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GUCY2C | c.420del p.M141* | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | called by mutect2, pindel, varscan2
- KIAA1755 | c.3461T>G p.L1154R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NFIA | c.15_16del p.C6Sfs*5 | Frame Shift Del (DEL) | VAF 76/344 reads (22%) | called by pindel, varscan2
- NFX1 | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRH | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RCN3 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- RPLP1 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RUNDC1 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SATL1 | c.1270A>C p.K424Q (on ENST00000395409; = p.K611Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- SDK2 | c.3997+1G>A p.X1333_splice | Splice Site (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- SEMG1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC23A2 | c.1428C>A p.S476R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SLC2A3 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 20/569 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2
- SPATA31A7 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); called by muse, mutect2
- STAG2 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SUN2 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TEX15 | c.5986G>A p.A1996T (on ENST00000256246; = p.A2379T on NM_001350162.2) | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UBE2F | c.100_101del p.D34Qfs*5 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by pindel, varscan2
- USP6NL | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ZNF593 | c.241dup p.R81Pfs*46 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel
- ADH1B | c.750C>T p.P250= | Silent (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- ANKRD20A1 | c.1872G>A p.V624= | Silent (SNP) | VAF 45/180 reads (25%) | called by muse, mutect2, varscan2
- ENG | c.1770C>T p.P590= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs370943570; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPD2 | c.1854T>C p.I618= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- SLC27A1 | c.765G>C p.L255= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- SLC38A8 | c.84C>A p.G28= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100230633; called by muse, mutect2, varscan2
- ZNF502 | c.276A>G p.E92= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- ZNF185 | c.1209-3463C>A | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
